Somatic mutation profile of tumor specimen TCGA-CV-A45Q-01A (aliquot TCGA-CV-A45Q-01A-11D-A24D-08) from TCGA case TCGA-CV-A45Q, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mouth, NOS; Tumor grade: G1; Age at diagnosis: 69.5 years (25,379 days).
Specimen TCGA-CV-A45Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d96b7423-03c0-4b7f-9ec9-0806a25b8609.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-A45Q-10A (Blood Derived Normal), aliquot TCGA-CV-A45Q-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a2ba4b3-6df9-4bd4-819b-9839a3002046

The open-access MAF lists 311 somatic variants for this specimen: 227 protein-altering or splice-affecting, 78 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 192, Silent 78, Nonsense Mutation 17, Frame Shift Del 6, Splice Site 6, Splice Region 4, Intron 4, 3'Flank 2, Translation Start Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAT1 | c.4879C>T p.R1627* | Nonsense Mutation (SNP) | VAF 3/14 reads (21%) | hotspot (GDC flag); catalogued as rs1340793072, COSV71673166; called by muse, mutect2
- ABCB1 | c.1108G>C p.D370H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV55946476, COSV55950927; called by muse, mutect2, varscan2
- ABCB8 | c.346G>T p.E116* (on ENST00000297504 / NM_001282291.2; = p.E99* on NM_007188.5) | Nonsense Mutation (SNP) | VAF 15/63 reads (24%) | catalogued as COSV52505836, COSV99874764; called by muse, mutect2, varscan2
- ABCG4 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1309476298, COSV100266911; called by muse, mutect2, varscan2
- ABLIM3 | c.161G>A p.C54Y | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV100448620; called by muse, mutect2, varscan2
- ABRAXAS1 | c.471A>C p.Q157H | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.511); catalogued as COSV100426924; called by muse, mutect2, varscan2
- AFAP1L2 | c.1816C>G p.P606A | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV100412813, COSV58418853; called by muse, mutect2, varscan2
- AJUBA | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV99401112; called by muse, mutect2
- ANKRD50 | c.1567G>C p.E523Q | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.23); catalogued as COSV101539003; called by muse, mutect2, varscan2
- ANO9 | c.240C>G p.I80M | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV100241119, COSV60448039; called by muse, mutect2, varscan2
- AP002512.3 | c.144+3C>G | Splice Region (SNP) | VAF 13/67 reads (19%) | catalogued as COSV100392622, COSV56567003; called by muse, mutect2, varscan2
- ARMC4 | c.1363C>T p.Q455* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99518859; called by muse, mutect2, varscan2
- ASXL3 | c.4894G>C p.E1632Q | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.307); catalogued as COSV52462181, COSV99325833; called by muse, mutect2, varscan2
- ATN1 | c.1978G>A p.G660R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.174); catalogued as COSV100755889, COSV63111613; called by muse, mutect2, varscan2
- ATP13A4 | c.3464A>T p.Q1155L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as COSV100710551; called by muse, mutect2, varscan2
- AZIN1 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 3/10 reads (30%) | catalogued as COSV100457684; called by muse, mutect2
- AZIN2 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); catalogued as rs1056872417, COSV99613614; called by muse, mutect2, varscan2
- BABAM1 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV63919977; called by muse, mutect2, varscan2
- BCAT2 | c.1119G>T p.Q373H | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100302490, COSV100302512; called by muse, varscan2
- BICD2 | c.596G>C p.R199T | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs1487654294, COSV100794211; called by muse, mutect2, varscan2
- BPIFA1 | c.516G>T p.R172S | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.192); catalogued as rs377508040, COSV100845652; called by muse, mutect2, varscan2
- BTNL9 | c.1372G>A p.G458R | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1487969391, COSV100576203; called by muse, mutect2, varscan2
- C11orf1 | c.432G>A p.M144I | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.294); catalogued as COSV99500117; called by muse, mutect2, varscan2
- C1QL1 | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99492806; called by muse, mutect2, varscan2
- C3 | c.419C>G p.T140S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV55578039, COSV99837038; called by muse, mutect2, varscan2
- C3orf56 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs770393141, COSV101228923; called by muse, mutect2, varscan2
- CAPN12 | c.1910C>G p.S637C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99400546; called by muse, mutect2, varscan2
- CAPN6 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.369); catalogued as COSV100136979; called by muse, mutect2, varscan2
- CARM1 | c.1665G>A p.M555I | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); catalogued as rs887868662, COSV53402590, COSV99450213; called by muse, mutect2, varscan2
- CBLN2 | c.92G>A p.C31Y | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1568249549, COSV99504524; called by muse, mutect2, varscan2
- CDC25C | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV100086830; called by muse, mutect2, varscan2
- CDC42EP4 | c.884C>G p.S295* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100231923; called by muse, mutect2
- CDH20 | c.1311C>G p.F437L | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV99404959, COSV99406056; called by muse, mutect2, varscan2
- CDYL2 | c.1204C>G p.L402V | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV101629603; called by muse, mutect2, varscan2
- CHD8 | c.4895C>T p.S1632L (on ENST00000646647 / NM_001170629.2; = p.S1353L on NM_020920.4) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100783814; called by muse, varscan2
- CIRBP | c.441G>C p.Q147H | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1167003689, COSV100309851; called by muse, mutect2, varscan2
- CNGB1 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV99205201; called by muse, mutect2, varscan2
- CNIH4 | c.69C>G p.F23L | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100837027, COSV100837072; called by muse, mutect2, varscan2
- CNTNAP2 | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.906); catalogued as rs375721700; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSAD | c.882G>C p.Q294H (on ENST00000444623 / NM_001244705.2; = p.Q321H on NM_015989.5) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99914905; called by muse, varscan2
- DEDD2 | c.487C>T p.R163W | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs537426887, COSV60142274; called by muse, mutect2
- DHX32 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as COSV99501832; called by muse, mutect2, varscan2
- DIS3 | c.1637C>T p.S546F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs779209129, COSV100899951; called by muse, mutect2, varscan2
- DNAH7 | c.10411G>A p.A3471T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100416433, COSV56781645; called by muse, mutect2, varscan2
- DNAJB7 | c.529G>C p.D177H | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as rs145804206, COSV99344342; called by muse, mutect2, varscan2
- DNAJC14 | c.1679C>T p.A560V | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV99670819; called by muse, mutect2, varscan2
- DNTTIP2 | c.124G>C p.D42H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV63283778; called by muse, mutect2
- DSCAM | c.843G>C p.E281D | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.987); catalogued as COSV101261014, COSV68023490; called by muse, mutect2, varscan2
- DSPP | c.865G>C p.D289H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.808); catalogued as COSV56811227, COSV99217697; called by muse, mutect2, varscan2
- DTNA | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99314067; called by mutect2, varscan2
- EEF1AKMT1 | c.257A>G p.Y86C | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101236942; called by muse, mutect2, varscan2
- EIF2S2 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as COSV66621482; called by mutect2, varscan2
- ENOX1 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV99816621; called by muse, mutect2, varscan2
- EPHA5 | c.1034G>C p.R345T | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV56640223, COSV99900167; called by muse, mutect2, varscan2
- ERC2 | c.2328G>C p.K776N | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV55656317, COSV99887444; called by muse, mutect2, varscan2
- ESR1 | c.950G>T p.S317I | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.645); catalogued as COSV99240278; called by muse, mutect2, varscan2
- EXT2 | c.643G>A p.G215S (on ENST00000343631; = p.G248S on NM_000401.3) | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as COSV100640655; called by muse, mutect2, varscan2
- F2R | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs770087836, COSV100058299; called by muse, mutect2, varscan2
- FAM133A | c.345C>G p.S115R | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as COSV100220535; called by muse, varscan2
- FANCD2OS | c.99C>G p.F33L | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.08); catalogued as COSV101090988, COSV101091762; called by muse, mutect2, varscan2
- FAT1 | c.2872C>T p.Q958* | Nonsense Mutation (SNP) | VAF 25/93 reads (27%) | catalogued as COSV71674995; called by muse, mutect2, varscan2
- FBLN2 | c.1925G>T p.R642L | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0.021); catalogued as COSV55488340; called by muse, mutect2, varscan2
- FLG | c.3893C>T p.S1298F | Missense Mutation (SNP) | VAF 52/219 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.108); catalogued as rs775671019, COSV100911878; called by muse, mutect2, varscan2
- FLNB | c.5794G>A p.E1932K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99914086; called by muse, mutect2, varscan2
- GASK1B | c.304C>G p.L102V | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.038); catalogued as COSV99647945; called by muse, mutect2, varscan2
- GDPD4 | c.293G>C p.G98A | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.82); catalogued as COSV100265487; called by muse, mutect2, varscan2
- GPR156 | c.1997C>G p.S666* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as COSV100251597; called by muse, mutect2, varscan2
- GSTA2 | c.37C>T p.R13W | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs771389883, COSV101534064; called by muse, mutect2, varscan2
- HLA-F | c.379G>C p.D127H | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.989); catalogued as COSV99466217; called by muse, mutect2, varscan2
- HNRNPL | c.1356-2A>G p.X452_splice | Splice Site (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99670457; called by muse, mutect2
- HPS6 | c.1786G>A p.G596R | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV100154938; called by muse, mutect2, varscan2
- HSPA12B | c.453G>A p.T151= | Splice Region (SNP) | VAF 20/94 reads (21%) | catalogued as rs766367065; called by muse, mutect2
- IDE | c.2445C>G p.I815M | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99794197; called by muse, mutect2, varscan2
- IL21 | c.168G>T p.L56F | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV99144468; called by muse, mutect2, varscan2
- IL6ST | c.2275T>C p.Y759H | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100410967; called by muse, mutect2, varscan2
- INTS6 | c.802A>T p.I268L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as CM142442, COSV100247187; called by muse, mutect2, varscan2
- ITGB1BP2 | c.623A>C p.H208P | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99339022; called by muse, varscan2
- KANSL1 | c.985_986del p.L329Efs*22 | Frame Shift Del (DEL) | VAF 16/119 reads (13%) | catalogued as rs281865473; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- KCNAB1 | c.1004G>A p.R335K (on ENST00000490337 / NM_172160.3; = p.R324K on NM_003471.3) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as COSV100204681; called by muse, mutect2, varscan2
- KCNH4 | c.2968G>C p.G990R | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as rs368768991; called by mutect2, varscan2
- KDM6A | c.676G>T p.E226* | Nonsense Mutation (SNP) | VAF 3/12 reads (25%) | catalogued as COSV65045384; called by muse, mutect2
- KHDC4 | c.1696G>A p.A566T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100850983; called by muse, mutect2, varscan2
- KIAA2026 | c.2561G>A p.R854K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as COSV101199141, COSV67354212; called by muse, mutect2, varscan2
- KIF16B | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100734714; called by muse, mutect2, varscan2
- KIF21B | c.1667T>A p.V556D | Missense Mutation (SNP) | VAF 68/143 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as COSV100144854; called by muse, mutect2, varscan2
- KIF4B | c.2111C>T p.T704M | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.245); catalogued as rs760342797, COSV101469362; called by muse, mutect2, varscan2
- KIF5C | c.1045G>C p.E349Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.944); catalogued as COSV101276086; called by muse, mutect2, varscan2
- KMT2B | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 27/128 reads (21%) | catalogued as COSV52889323; called by muse, mutect2, varscan2
- KSR2 | c.980C>T p.T327M | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs765576718, COSV60370984; called by muse, mutect2, varscan2
- LAMB1 | c.599C>G p.S200* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as COSV55962036, COSV99741362; called by muse, mutect2, varscan2
- LANCL3 | c.905A>G p.Y302C | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101065712; called by muse, mutect2
- LPIN3 | c.961C>T p.L321F | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs775921131, COSV100953079; called by muse, mutect2, varscan2
- LPP | c.1710G>A p.E570= | Splice Region (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100447903; called by muse, mutect2
- LRP2 | c.4174G>C p.D1392H | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV99789582; called by muse, mutect2, varscan2
- LRP4 | c.769G>C p.D257H | Missense Mutation (SNP) | VAF 35/136 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV101066763; called by muse, mutect2, varscan2
- LRRC73 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.035); catalogued as rs1416037132, COSV52501071; called by muse, varscan2
- LRRK1 | c.5044G>C p.A1682P | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV52603450, COSV52624529, COSV99441801; called by muse, mutect2, varscan2
- LRRTM4 | c.1742C>T p.P581L | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as rs1316074666, COSV101299072, COSV101299177; called by muse, mutect2, varscan2
- LYST | c.5839C>G p.H1947D | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV101089992; called by muse, mutect2, varscan2
- MAP3K6 | c.2071C>G p.H691D | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100709339; called by muse, mutect2, varscan2
- MARCKSL1 | c.548A>T p.E183V | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV100269630; called by muse, mutect2, varscan2
- MARCKSL1 | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100269631; called by muse, mutect2, varscan2
- MAST1 | c.1918G>C p.E640Q | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52240407, COSV99263384; called by muse, mutect2, varscan2
- MED12L | c.4328T>A p.L1443* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99854051; called by muse, mutect2, varscan2
- MICAL2 | c.2228C>T p.S743L | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99818014; called by muse, varscan2
- MMP16 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs760497058, COSV54161518, COSV99688817; called by muse, mutect2, varscan2
- MROH2B | c.4398G>T p.Q1466H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV101270833, COSV68186294; called by muse, mutect2, varscan2
- MROH2B | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.109); catalogued as rs1342429120, COSV101270834; called by muse, mutect2, varscan2
- MRPS22 | c.397G>C p.E133Q (on ENST00000310776 / NM_001363893.1; = p.E134Q on NM_020191.4) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.857); catalogued as COSV100169152; called by muse, mutect2, varscan2
- MTHFD2 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs771539434, COSV99902829; called by muse, mutect2, varscan2
- MTUS2 | c.3826A>G p.K1276E (on ENST00000612955 / NM_001366650.1; = p.K255E on NM_015233.6) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as rs1411934931, COSV101070900; called by muse, mutect2, varscan2
- MYH1 | c.1008+2T>A p.X336_splice | Splice Site (SNP) | VAF 16/88 reads (18%) | catalogued as COSV99876528; called by muse, mutect2, varscan2
- MYH6 | c.2683G>A p.A895T | Missense Mutation (SNP) | VAF 56/97 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV100676831; called by muse, mutect2, varscan2
- MYH9 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53382462, COSV53382648; called by muse, mutect2, varscan2
- MYNN | c.457C>G p.R153G | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as COSV100582223, COSV62991224; called by muse, mutect2, varscan2
- MYO1A | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs776772506, COSV100271127; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO5A | c.5425C>T p.R1809* | Nonsense Mutation (SNP) | VAF 14/45 reads (31%) | catalogued as COSV62562130; called by muse, mutect2, varscan2
- MYOCD | c.883C>A p.L295M | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100591128; called by muse, mutect2, varscan2
- MYRIP | c.1842G>C p.E614D | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs761387097, COSV100219629; called by muse, mutect2, varscan2
- NBEAL1 | c.6851G>C p.R2284T | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100074347; called by muse, mutect2, varscan2
- NEFM | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99647466; called by muse, mutect2, varscan2
- NELL1 | c.2026C>G p.P676A | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.283); catalogued as COSV100123256; called by muse, mutect2, varscan2
- NEURL1 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as rs144450414; called by muse, mutect2, varscan2
- NIPAL3 | c.962C>T p.T321M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs762007576, COSV99135402; called by muse, mutect2, varscan2
- NKAPL | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100642557; called by muse, mutect2, varscan2
- NRXN3 | c.970G>C p.E324Q (on ENST00000557594 / NM_001272020.2; = p.E956Q on NM_004796.6) | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV99820594; called by muse, mutect2, varscan2
- OR2A7 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as rs754356545, COSV101512223, COSV101512231; called by muse, mutect2, varscan2
- OR51B5 | c.680C>A p.A227D | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100332623; called by muse, mutect2, varscan2
- P2RX5 | c.631G>C p.V211L | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as COSV99835893; called by muse, mutect2, varscan2
- PARM1 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV100268357; called by muse, mutect2
- PCDH7 | c.1469C>G p.S490W | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100688529; called by muse, mutect2, varscan2
- PCDHB9 | c.1897C>T p.R633C | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as rs782628377; called by muse, varscan2
- PCLO | c.8680G>C p.D2894H | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); catalogued as rs549765960, COSV61639441; called by muse, mutect2, varscan2
- PDGFRA | c.769G>A p.G257S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.914); catalogued as COSV57266836; called by muse, mutect2, varscan2
- PEAK1 | c.3976G>C p.D1326H | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.092); catalogued as COSV100433281; called by muse, mutect2, varscan2
- PEG3 | c.481+2T>G p.X161_splice | Splice Site (SNP) | VAF 11/43 reads (26%) | catalogued as COSV99689804; called by muse, mutect2, varscan2
- PGK1 | c.642-2A>C p.X214_splice | Splice Site (SNP) | VAF 14/37 reads (38%) | catalogued as COSV100965356; called by muse, varscan2
- PGRMC1 | c.17T>C p.V6A | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); catalogued as COSV99483587; called by muse, mutect2, varscan2
- PHF1 | c.288G>C p.E96D | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.506); catalogued as COSV100992609, COSV100992653; called by muse, mutect2, varscan2
- PHF3 | c.3398C>G p.S1133C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100013698; called by muse, mutect2, varscan2
- PHLDB1 | c.2599G>A p.E867K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV100616684; called by muse, mutect2, varscan2
- PHLDB1 | c.2986G>A p.V996M | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as rs782253532, COSV100616348; called by muse, mutect2, varscan2
- PIK3R5 | c.2416C>A p.Q806K | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV99353668; called by muse, mutect2, varscan2
- PNMA2 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV101580638; called by muse, mutect2, varscan2
- POM121 | c.3107C>G p.S1036W (on ENST00000434423; = p.S771W on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV99987660, COSV99988868; called by muse, mutect2, varscan2
- PPP2R3C | c.307C>A p.L103M | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99808824; called by muse, mutect2, varscan2
- PSMC3 | c.252G>C p.K84N | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.776); catalogued as rs1265080785; called by muse, varscan2
- PTBP2 | c.1351G>A p.G451R (on ENST00000426398 / NM_001300986.2; = p.G443R on NM_021190.4) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100930245; called by muse, mutect2, varscan2
- PTPN21 | c.765-1G>A p.X255_splice | Splice Site (SNP) | VAF 18/43 reads (42%) | catalogued as COSV100162304; called by muse, varscan2
- QSOX2 | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100699830; called by muse, mutect2, varscan2
- RFWD3 | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV100736283; called by muse, mutect2, varscan2
- RFWD3 | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs755233927, COSV100736284; called by muse, mutect2, varscan2
- RNASE4 | c.77C>G p.S26C | Missense Mutation (SNP) | VAF 80/167 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.159); catalogued as COSV100489430; called by muse, mutect2, varscan2
- RNLS | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV100076828; called by mutect2, varscan2
- RPS6KA5 | c.1615G>A p.G539R | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV100002937; called by muse, mutect2, varscan2
- RPTOR | c.2630C>T p.S877F | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.735); catalogued as rs768404459, COSV100156818; called by muse, mutect2, varscan2
- RYR3 | c.7687C>A p.P2563T (on ENST00000389232; = p.P2564T on NM_001036.6) | Missense Mutation (SNP) | VAF 2/15 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV66795239; called by muse, mutect2
- SBDS | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.843); catalogued as COSV99886125; called by muse, mutect2, varscan2
- SCN9A | c.2103A>C p.E701D (on ENST00000303354; = p.E690D on NM_002977.3) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV100313583, COSV100314766; called by muse, mutect2, varscan2
- SDC3 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV100232388; called by muse, mutect2, varscan2
- SDS | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.569); catalogued as COSV99981125; called by muse, mutect2, varscan2
- SEMA3G | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99202526; called by muse, mutect2, varscan2
- SEMA4G | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.472); catalogued as COSV52972433; called by muse, mutect2
- SEMA6D | c.1450G>C p.D484H | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100317329; called by muse, mutect2
- SENP5 | c.2017G>A p.V673I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs1419383167, COSV100052165, COSV100052276; called by muse, mutect2, varscan2
- SEPTIN2 | c.735G>T p.L245F | Missense Mutation (SNP) | VAF 60/206 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV100764992, COSV63632753; called by muse, varscan2
- SERPINB10 | c.240C>G p.F80L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV53073993; called by muse, mutect2
- SI | c.2989G>A p.A997T | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV100016500; called by muse, mutect2, varscan2
- SLC22A6 | c.1397G>C p.R466P | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100842881; called by muse, mutect2
- SLC9A3 | c.2351C>T p.S784L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99376477; called by muse, mutect2, varscan2
- SMAD3 | c.190T>A p.C64S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100529312; called by muse, mutect2, varscan2
- SMARCA2 | c.4760C>T p.T1587M | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.412); catalogued as rs753433101, COSV56645186; called by muse, mutect2, varscan2
- SMCHD1 | c.1605G>T p.L535F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99862148; called by muse, mutect2, varscan2
- SOCS3 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV58270928; called by muse, mutect2, varscan2
- SRCAP | c.7484C>G p.S2495C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs201185965, COSV52672582; called by muse, mutect2, varscan2
- SSTR1 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1258904127, COSV57458125; called by muse, mutect2, varscan2
- SSTR2 | c.722G>C p.R241P | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100192146; called by muse, mutect2, varscan2
- STRIP1 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV100873981; called by muse, mutect2, varscan2
- STRN4 | c.2021C>G p.S674C | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54420687; called by muse, varscan2
- STX17 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 9/49 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as COSV52285927; called by muse, mutect2, varscan2
- SYNE1 | c.25270C>T p.L8424F (on ENST00000367255 / NM_182961.4; = p.L8376F on NM_033071.3) | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.19); catalogued as COSV99573099; called by muse, mutect2, varscan2
- SYT1 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV99696586; called by muse, mutect2
- TAPBPL | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1357772493, COSV99869450; called by muse, mutect2, varscan2
- TARS2 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs762368446, COSV100946045; called by muse, mutect2, varscan2
- TBCE | c.665C>G p.S222C (on ENST00000366601; = p.S285C on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.114); catalogued as COSV100783185; called by muse, mutect2, varscan2
- TBKBP1 | c.704C>A p.A235D | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV100659180; called by muse, mutect2
- TCEAL5 | c.614A>C p.Y205S | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV101013161; called by muse, varscan2
- TGFB1I1 | c.734G>A p.R245H (on ENST00000394863 / NM_001042454.3; = p.R228H on NM_015927.4) | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV100691159; called by muse, mutect2, varscan2
- TLN2 | c.5546G>C p.G1849A | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.099); catalogued as COSV100169642; called by muse, mutect2, varscan2
- TMEM132A | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99136386; called by muse, mutect2, varscan2
- TMEM215 | c.441G>T p.Q147H | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100713219; called by mutect2, varscan2
- TOGARAM1 | c.1858C>G p.Q620E | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as COSV61888692; called by muse, mutect2, varscan2
- TP53 | c.75-1G>C p.X25_splice | Splice Site (SNP) | VAF 17/50 reads (34%) | catalogued as COSV53294543, COSV99037345; called by muse, mutect2, varscan2
- TRIP10 | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.952); catalogued as rs764626879, COSV57575464; called by muse, mutect2
- TRNT1 | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99285842; called by muse, mutect2, varscan2
- TRPC4 | c.2666G>C p.R889P (on ENST00000379705 / NM_016179.4; = p.R894P on NM_003306.3) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.071); catalogued as rs761582713, COSV100157457, COSV58994204; called by muse, mutect2, varscan2
- TRPC6 | c.1584G>A p.M528I | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV100723719; called by muse, mutect2, varscan2
- TSC2 | c.1210C>T p.Q404* | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | catalogued as rs45457701, CM090991, COSV54755624; ClinVar: not provided; called by muse, mutect2, varscan2
- TSHB | c.237C>A p.Y79* | Nonsense Mutation (SNP) | VAF 32/87 reads (37%) | catalogued as COSV99859081; called by muse, mutect2, varscan2
- TTC27 | c.476T>G p.I159R | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.347); catalogued as COSV100513357; called by muse, mutect2, varscan2
- UACA | c.1329G>C p.K443N | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100537624; called by muse, mutect2, varscan2
- UBQLN4 | c.258G>A p.Q86= | Splice Region (SNP) | VAF 13/41 reads (32%) | catalogued as COSV100849112; called by muse, mutect2, varscan2
- UBR5 | c.425G>A p.G142E | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99641729; called by muse, mutect2, varscan2
- USP7 | c.1441G>C p.D481H | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61214251; called by muse, mutect2, varscan2
- UTP20 | c.6871C>G p.Q2291E | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV55378964, COSV99882138; called by muse, mutect2, varscan2
- VCAN | c.2155G>C p.E719Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV99426700; called by muse, mutect2, varscan2
- VPS13C | c.8415C>G p.F2805L (on ENST00000644861 / NM_020821.3; = p.F2762L on NM_017684.5) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99829474; called by muse, mutect2, varscan2
- WDR33 | c.1210C>T p.R404* | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as COSV59246317; called by muse, mutect2
- WRN | c.587del p.R196Pfs*32 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | catalogued as COSV99989455; called by mutect2, pindel, varscan2
- XKR3 | c.1314G>T p.R438S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); catalogued as COSV100509333; called by muse, mutect2, varscan2
- YLPM1 | c.2002C>G p.P668A | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.079); catalogued as COSV99460682; called by muse, mutect2, varscan2
- YLPM1 | c.2107C>A p.P703T | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.23); catalogued as COSV99460691; called by muse, mutect2, varscan2
- ZBTB5 | c.1399G>C p.E467Q | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.42); catalogued as COSV100312873; called by muse, mutect2, varscan2
- ZMYM1 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.904); catalogued as COSV100721026; called by mutect2, varscan2
- ZNF248 | c.761G>A p.S254N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs556979147, COSV100627674; called by muse, mutect2, varscan2
- ZNF444 | c.310T>C p.S104P | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.597); catalogued as COSV100442706; called by muse, mutect2, varscan2
- ZNF492 | c.88C>A p.P30T | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV101514032, COSV71762303; called by muse, mutect2, varscan2
- ZNF573 | c.895G>A p.E299K (on ENST00000536220 / NM_001172692.1; = p.E241K on NM_152360.3) | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as rs1393135898, COSV100265761; called by muse, mutect2, varscan2
- ZNF624 | c.673C>G p.Q225E | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV100257349; called by muse, mutect2, varscan2
- ZNF71 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); catalogued as COSV60146278, COSV60147995; called by muse, mutect2, varscan2
- ZNRF4 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs541728675, COSV99706564; called by muse, mutect2, varscan2
- AJUBA | c.905del p.S302Wfs*108 | Frame Shift Del (DEL) | VAF 33/65 reads (51%) | called by mutect2, pindel, varscan2
- CGB2 | c.85C>A p.P29T | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- HS3ST3A1 | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- OCM2 | c.1del p.M1? | Frame Shift Del (DEL) | VAF 7/35 reads (20%) | called by mutect2, pindel, varscan2
- RBAK | c.2093del p.Q698Rfs*9 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | called by mutect2, pindel, varscan2
- SI | c.3875_3881del p.Y1292Lfs*48 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- B4GALNT1 | c.1155G>A p.A385= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as rs771293936, COSV57542262; called by muse, mutect2
- C1orf105 | c.93C>T p.L31= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs531541544, COSV99278321; called by muse, mutect2
- CCDC85B | c.608G>A p.*203= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as COSV100440952; called by muse, mutect2
- CCT2 | c.1563C>T p.I521= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV100167756; called by muse, mutect2, varscan2
- CDC42BPG | c.2136G>A p.L712= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as COSV100712125; called by muse, mutect2, varscan2
- CRB1 | c.1605G>A p.L535= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV100958009; called by muse, mutect2, varscan2
- CUL1 | c.2175G>A p.L725= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV100296820; called by muse, mutect2, varscan2
- CUL7 | c.2472C>G p.L824= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV99539001; called by muse, mutect2, varscan2
- DCC | c.388C>A p.R130= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV100501855, COSV59091972; called by muse, mutect2, varscan2
- DIS3L | c.2076C>T p.V692= (on ENST00000319212 / NM_001143688.3; = p.V609= on NM_133375.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as rs775837616, COSV100055455; called by muse, mutect2, varscan2
- DNAH7 | c.1908C>T p.L636= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as rs371183223; called by muse, mutect2, varscan2
- DNAI4 | c.2238T>A p.A746= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV100925494; called by muse, mutect2, varscan2
- DNAJB5 | c.591C>G p.L197= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV100258008; called by muse, mutect2, varscan2
- DUOX1 | c.2406G>A p.L802= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV58479488; called by muse, mutect2, varscan2
- ENTR1 | c.546C>T p.T182= (on ENST00000357365 / NM_001039707.2; = p.T159= on NM_006643.4) | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs371136291, COSV100048285; called by muse, mutect2, varscan2
- EPHX4 | c.636G>A p.L212= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV100952742; called by muse, mutect2
- FGD5 | c.2028T>C p.S676= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV99548711; called by muse, mutect2, varscan2
- GAS8 | c.849C>G p.L283= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs1281552125, COSV51943191, COSV99244102; called by muse, mutect2, varscan2
- GLRA4 | c.517C>T p.L173= | Silent (SNP) | VAF 39/68 reads (57%) | catalogued as rs777731627, COSV101009675; called by muse, mutect2, varscan2
- GPR61 | c.798C>T p.V266= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV100879933; called by muse, mutect2, varscan2
- GRIA1 | c.159G>A p.P53= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs755342972, COSV53591151; called by muse, mutect2, varscan2
- HIPK1 | c.1528C>T p.L510= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV100479456; called by muse, mutect2, varscan2
- HMX3 | c.420G>A p.L140= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV100774155; called by muse, mutect2, varscan2
- ICAM3 | c.1527C>T p.V509= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV99349191; called by muse, mutect2, varscan2
- IGIP | c.66C>T p.V22= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV100322963; called by muse, mutect2, varscan2
- INO80 | c.4122C>T p.D1374= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs775846922, COSV100731978; called by muse, mutect2, varscan2
- KCNG2 | c.258C>T p.R86= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100301975; called by muse, mutect2, varscan2
- KCNJ5 | c.909C>T p.V303= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV100610752; called by muse, mutect2, varscan2
- KCNK9 | c.366G>A p.L122= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs1457963355, COSV100270895; called by muse, mutect2
- KRTAP19-3 | c.141C>A p.G47= | Silent (SNP) | VAF 51/230 reads (22%) | catalogued as COSV100477607; called by muse, mutect2, varscan2
- LCT | c.4572G>A p.Q1524= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV99930033; called by muse, mutect2, varscan2
- LENG9 | c.1053G>A p.G351= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV100002884; called by muse, mutect2, varscan2
- LGSN | c.1023G>A p.G341= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as COSV65726548; called by muse, mutect2, varscan2
- LRP2 | c.1110G>C p.L370= | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as COSV99789583; called by muse, mutect2, varscan2
- LRP8 | c.1245G>A p.K415= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV100036758; called by muse, mutect2, varscan2
- LRRC71 | c.1437C>T p.L479= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV100168581; called by muse, mutect2
- MAN2A2 | c.3180C>G p.L1060= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV100847939; called by muse, mutect2, varscan2
- MCF2L2 | c.312C>T p.I104= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV61063604; called by muse, mutect2, varscan2
- MIDN | c.978G>A p.S326= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs45524034, COSV99960328; called by muse, mutect2, varscan2
- MMP15 | c.1224C>T p.I408= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs907458455, COSV54679728; called by muse, mutect2, varscan2
- MUC20 | c.1422C>G p.V474= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV100291392, COSV100291415; called by muse, mutect2, varscan2
- MYBL2 | c.1893C>G p.L631= | Silent (SNP) | VAF 64/223 reads (29%) | catalogued as COSV99406595; called by muse, mutect2, varscan2
- MYOM3 | c.2089C>T p.L697= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV100293349, COSV58402120; called by muse, mutect2, varscan2
- NPHP1 | c.1209C>T p.L403= (on ENST00000393272 / NM_207181.4; = p.L404= on NM_000272.5) | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV100338344; called by muse, mutect2, varscan2
- OR1A2 | c.555G>C p.L185= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as rs1567521471, COSV101126374; called by muse, mutect2, varscan2
- PHLDB1 | c.1116C>T p.L372= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as COSV61877722, COSV61881658; called by muse, varscan2
- PLA2G5 | c.336G>T p.R112= | Silent (SNP) | VAF 23/82 reads (28%) | catalogued as COSV100908260; called by muse, mutect2, varscan2
- PLEKHA5 | c.1977C>A p.L659= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs139664305, COSV100164487; called by muse, mutect2, varscan2
- PLXNA4 | c.1581T>C p.C527= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs776775617, COSV100325913; called by muse, mutect2, varscan2
- PRX | c.3450C>T p.I1150= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV99396900; called by muse, mutect2, varscan2
- RABGGTA | c.1038G>A p.T346= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs368480869, COSV99397750; called by muse, mutect2, varscan2
- RASD1 | c.120C>T p.I40= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as COSV99245850; called by muse, mutect2, varscan2
- RIN3 | c.2547G>A p.L849= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV99379674; called by muse, mutect2, varscan2
- SAMD4A | c.1161G>C p.L387= | Silent (SNP) | VAF 38/69 reads (55%) | catalogued as COSV99200761; called by muse, mutect2, varscan2
- SCN1A | c.999A>G p.A333= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV100321292; called by muse, mutect2
- SEMG2 | c.1551A>G p.Q517= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs756351304, COSV101034176; called by muse, mutect2, varscan2
- SLC38A5 | c.165C>T p.F55= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV100476668; called by muse, mutect2, varscan2
- SLC5A9 | c.1575G>A p.L525= | Silent (SNP) | VAF 26/129 reads (20%) | catalogued as COSV52581736, COSV99361822; called by muse, mutect2, varscan2
- SMARCA5 | c.1689T>C p.G563= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as COSV99304027; called by muse, mutect2, varscan2
- SMG6 | c.1587G>A p.Q529= | Silent (SNP) | VAF 42/147 reads (29%) | catalogued as rs1402569278, COSV99558499; called by muse, mutect2, varscan2
- SORBS2 | c.2277C>A p.R759= | Silent (SNP) | VAF 51/186 reads (27%) | catalogued as COSV99511940; called by muse, mutect2, varscan2
- STIMATE | c.615C>G p.V205= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV100753819; called by muse, mutect2, varscan2
- SUPT20H | c.1074T>A p.L358= (on ENST00000350612 / NM_001014286.3; = p.L359= on NM_017569.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100634771; called by mutect2, varscan2
- SYNRG | c.987G>A p.G329= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs1235092759; called by muse, mutect2, varscan2
- TBC1D10A | c.387G>A p.V129= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV99304848; called by muse, mutect2, varscan2
- TIGAR | c.12C>T p.F4= | Silent (SNP) | VAF 29/103 reads (28%) | catalogued as rs1366407595, COSV99463857; called by muse, mutect2, varscan2
- TRAV40 | c.195G>A p.Q65= | Silent (SNP) | VAF 42/85 reads (49%) | called by muse, mutect2, varscan2
- TYMS | c.594C>A p.L198= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV51894775, COSV99201130; called by muse, varscan2
- UBB | c.579G>A p.Q193= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as rs376813261, COSV100141690; called by muse, varscan2
- VCAN | c.1800C>G p.V600= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV99426698; called by muse, mutect2, varscan2
- WDR59 | c.711C>G p.V237= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs748043809, COSV100049573; called by muse, varscan2
- XIRP2 | c.8826C>T p.R2942= (on ENST00000628543; = p.R3117= on NM_152381.6) | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs1241155334, COSV54698627; called by muse, mutect2, varscan2
- ZACN | c.486C>G p.L162= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV100135535, COSV58035181; called by muse, mutect2, varscan2
- ZAN | c.2808C>T p.I936= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as COSV100770000; called by muse, varscan2
- ZBED8 | c.918A>C p.P306= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV101283536; called by muse, mutect2, varscan2
- ZFYVE28 | c.1824G>A p.E608= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV52109486, COSV99343308; called by muse, mutect2, varscan2
- ZNF354C | c.897G>A p.P299= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as rs746830976, COSV59608186; called by muse, mutect2, varscan2
- ZPBP2 | c.288G>C p.V96= (on ENST00000348931 / NM_199321.3; = p.V74= on NM_198844.3) | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100818545, COSV62375509; called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73701293 G>C | 3'Flank (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- ATP7A | c.-21-8862A>C | Intron (SNP) | VAF 9/25 reads (36%) | catalogued as COSV100431326; called by muse, mutect2, varscan2
- FHL2 | c.-76+39G>A | Intron (SNP) | VAF 5/14 reads (36%) | catalogued as rs1156777824, COSV100363087; called by muse, varscan2
- MIR1270 | chr19:20397675 G>C | 3'Flank (SNP) | VAF 11/41 reads (27%) | catalogued as rs903682383; called by muse, mutect2, varscan2
- PDE4D | c.456-140832C>T | Intron (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100507933; called by muse, mutect2, varscan2
- PIK3AP1 | c.1376-4414G>A | Intron (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100226048; called by muse, varscan2
